MMRF case MMRF_1475 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8db0ed0d-03bb-4bc6-917d-4bd861472ed1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.1 years (25,610 days); ISS stage: II; Days to last known disease status: 1 day; Days to last follow up: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (2 entries)
- Days to follow up: -21 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Immunoglobulin A 56.1 g/L.
- Immunoglobulin G 2.58 g/L.
- Glucose 5.61 mmol/L.
- Platelets 151 ×10⁹/L.
- Lactate Dehydrogenase 1.97 µkat/L.
- Creatinine 70.7 µmol/L.
- Immunoglobulin M 0.05 g/L.
- Total Protein 10.7 g/dL.
- Leukocytes 5.01 ×10⁹/L.
- Calcium 2.73 mmol/L.
- C-Reactive Protein 0.113 mg/dL.
- Absolute Neutrophil 3.6 ×10⁹/L.
- Albumin 30 g/L.
- Hemoglobin 5.15 mmol/L.
- Beta 2 Microglobulin 5.21 µg/mL.
- Blood Urea Nitrogen 3.57 mmol/L.
- M Protein 5.5 g/dL.

Other clinical attributes
- Day -21: Weight: 58 kg; Height: 156 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Bladder Cancer.

Biospecimens (1 sample)
- Sample MMRF_1475_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
